Somatic mutation profile of tumor specimen TARGET-10-PARCKV-09A (aliquot TARGET-10-PARCKV-09A-01D) from TARGET case TARGET-10-PARCKV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,563 days).
Specimen TARGET-10-PARCKV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e37c30f-a386-4024-9ad9-7d8288237414.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCKV-10A (Blood Derived Normal), aliquot TARGET-10-PARCKV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a58fa23-b208-4202-9e91-6f61d5a7777f

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- UBL7 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as rs755501444, COSV63706862; called by muse, mutect2, varscan2
- H1-5 | c.477_478insGATT p.K160Dfs*2 | Frame Shift Ins (INS) | VAF 33/108 reads (31%) | called by mutect2, pindel, varscan2
- ENPP2 | c.12C>T p.H4= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1045880058; called by muse, mutect2
- HYDIN | c.9903C>T p.I3301= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs575084031, COSV101151611; called by muse, mutect2, varscan2
- PNN | c.894G>A p.V298= | Silent (SNP) | VAF 70/154 reads (45%) | catalogued as rs748055088; called by muse, mutect2, varscan2
